CPTAC case C3N-03839 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2525bfef-6962-4b7f-8e80-6186400ce624

Demographics
Sex at birth: female; Race: asian; Year of birth: 1963; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 54.6 years (19,956 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,858 days (5.1 years); Progression or recurrence: yes; Days to last follow up: 1,858 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 3 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 29; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 359 days; Disease response: Stable Disease; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 696 days (1.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 430 days (1.2 years); Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 696 days (1.9 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,081 days (3.0 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,431 days (3.9 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,858 days (5.1 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 66 kg; Height: 168 cm; BMI: 23.38.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03839-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 63 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03839-21: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3N-03839-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 45 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03839-22: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3N-03839-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 44 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03839-25: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3N-03839-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
